Somatic mutation profile of tumor specimen 48d1b543-dbf6-4594-b34a-d0e30a (aliquot 48d1b543-dbf6-4594-b34a-d0e30a_D6) from CPTAC case 05BR009, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 63.8 years (23,299 days).
Specimen 48d1b543-dbf6-4594-b34a-d0e30a: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 999cc072-b40f-4c6c-bd38-6286a9337f6d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen a1e9c072-ec07-4215-bfc3-5a65eb (Blood Derived Normal), aliquot a1e9c072-ec07-4215-bfc3-5a65eb_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1c37269-784e-4b8c-bbc4-61ba6bf2b0b8

The open-access MAF lists 61 somatic variants for this specimen: 42 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 18, Nonsense Mutation 4, Splice Region 2, Frame Shift Ins 2, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH1 | c.2029dup p.Q677Pfs*11 | Frame Shift Ins (INS) | VAF 36/217 reads (17%) | catalogued as rs1555517100; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- EHMT1 | c.3046C>T p.R1016* | Nonsense Mutation (SNP) | VAF 62/768 reads (8%) | catalogued as rs1429360126; ClinVar: pathogenic; called by muse, mutect2
- PIK3CA | c.1035T>A p.N345K | Missense Mutation (SNP) | VAF 57/155 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs121913284, COSV55873276; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ARSD | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54199433, COSV54200061; called by muse, mutect2
- ATP12A | c.2804C>T p.T935M | Missense Mutation (SNP) | VAF 36/190 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs761472175; called by muse, mutect2, varscan2
- ATP13A2 | c.2014G>A p.D672N | Missense Mutation (SNP) | VAF 38/488 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.027); catalogued as rs774061653; called by muse, mutect2
- GLI3 | c.3851C>T p.T1284I | Missense Mutation (SNP) | VAF 60/568 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs1345171343; called by muse, mutect2, varscan2
- HPN | c.685G>A p.G229S | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.077); catalogued as rs1349868053; called by muse, mutect2
- LINGO2 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 20/229 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as rs139845137; called by muse, mutect2, varscan2
- MAGEA12 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 30/254 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.313); catalogued as rs1434715732, COSV63294268; called by mutect2, varscan2
- MAP4K4 | c.3292G>A p.D1098N (on ENST00000347699 / NM_001242559.2; = p.D1016N on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV56333964; called by muse, mutect2, varscan2
- PCNX2 | c.6190G>A p.V2064I | Missense Mutation (SNP) | VAF 207/646 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.26); catalogued as rs528123440, COSV99266795; called by muse, mutect2, varscan2
- RAB23 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 31/254 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.263); catalogued as rs150655349; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RIMBP2 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 34/256 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs370977982, COSV99899668; called by muse, mutect2, varscan2
- SACS | c.6088C>G p.P2030A | Missense Mutation (SNP) | VAF 10/230 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as COSV66543120; called by muse, mutect2
- SEPHS1 | c.800C>A p.T267K | Missense Mutation (SNP) | VAF 44/360 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59259173; called by muse, mutect2, varscan2
- SLC6A17 | c.305A>G p.Y102C | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1451950736, COSV58993193; called by muse, mutect2, varscan2
- SPTA1 | c.3166C>T p.R1056C | Missense Mutation (SNP) | VAF 24/373 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as rs762361277, COSV63754736, COSV63758648; ClinVar: uncertain significance; called by muse, mutect2
- SYNM | c.1001C>G p.P334R | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV60369159; called by muse, mutect2
- TAF10 | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as rs772287208, COSV54990928; called by muse, mutect2, varscan2
- TMEM63B | c.1816G>A p.E606K | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV52480310; called by muse, mutect2
- TRPM1 | c.3082+1G>A p.X1028_splice | Splice Site (SNP) | VAF 5/70 reads (7%) | catalogued as rs779821510, COSV56634876; ClinVar: uncertain significance; called by muse, mutect2
- ZNF710 | c.1630G>A p.V544M | Missense Mutation (SNP) | VAF 47/225 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs746411531, COSV51562658; called by muse, mutect2, varscan2
- C18orf63 | c.1703G>A p.G568E | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CBFB | c.165+6T>C | Splice Region (SNP) | VAF 8/31 reads (26%) | called by muse, mutect2, varscan2
- CHRNB1 | c.143T>A p.V48E | Missense Mutation (SNP) | VAF 72/665 reads (11%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- DISP3 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- EIF4E1B | c.44A>T p.E15V | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); called by muse, mutect2
- EML2 | c.146dup p.L50Afs*58 | Frame Shift Ins (INS) | VAF 29/280 reads (10%) | called by mutect2, pindel
- EPX | c.197C>A p.S66* | Nonsense Mutation (SNP) | VAF 150/687 reads (22%) | called by mutect2, varscan2
- FAM120A | c.1808G>C p.R603T | Missense Mutation (SNP) | VAF 32/338 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- GABRE | c.1244G>A p.S415N | Missense Mutation (SNP) | VAF 11/243 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0.011); called by muse, mutect2
- GIT1 | c.460T>A p.S154T | Missense Mutation (SNP) | VAF 68/679 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.479); called by muse, mutect2
- MAMLD1 | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 68/583 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- MTMR11 | c.756T>A p.H252Q (on ENST00000439741 / NM_001145862.2; = p.H180Q on NM_181873.3) | Missense Mutation (SNP) | VAF 95/290 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- NES | c.4627G>A p.E1543K | Missense Mutation (SNP) | VAF 41/491 reads (8%) | SIFT tolerated (0.84); PolyPhen benign (0.001); called by muse, mutect2
- OR4D5 | c.482C>A p.A161E | Missense Mutation (SNP) | VAF 63/561 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- PNPLA6 | c.2141C>T p.A714V (on ENST00000414982 / NM_001166111.2; = p.A666V on NM_006702.5) | Missense Mutation (SNP) | VAF 100/261 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- SCT | c.174C>T p.S58= | Splice Region (SNP) | VAF 22/230 reads (10%) | called by muse, mutect2
- SH2D3C | c.136G>C p.E46Q | Missense Mutation (SNP) | VAF 40/422 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2
- SPEN | c.3022G>T p.E1008* | Nonsense Mutation (SNP) | VAF 16/148 reads (11%) | called by muse, mutect2
- USP25 | c.2605C>T p.Q869* | Nonsense Mutation (SNP) | VAF 5/46 reads (11%) | called by muse, mutect2, varscan2
- AJUBA | c.495C>A p.I165= | Silent (SNP) | VAF 62/152 reads (41%) | called by muse, mutect2, varscan2
- APOB | c.3280C>T p.L1094= | Silent (SNP) | VAF 164/568 reads (29%) | called by muse, mutect2, varscan2
- B3GNT3 | c.180G>A p.P60= | Silent (SNP) | VAF 69/231 reads (30%) | catalogued as rs200510528; called by muse, mutect2, varscan2
- B4GALNT2 | c.1413C>T p.G471= | Silent (SNP) | VAF 32/270 reads (12%) | catalogued as rs536287109, COSV55925225; called by muse, mutect2
- CCDC85A | c.588C>T p.L196= | Silent (SNP) | VAF 10/219 reads (5%) | catalogued as rs1479017307; called by muse, mutect2
- CCDC88C | c.1219C>A p.R407= | Silent (SNP) | VAF 76/238 reads (32%) | called by mutect2, varscan2
- CDADC1 | c.888C>T p.F296= | Silent (SNP) | VAF 20/257 reads (8%) | catalogued as rs778795376, COSV51911004; called by muse, mutect2
- CFHR1 | c.462A>G p.Q154= | Silent (SNP) | VAF 32/347 reads (9%) | called by muse, mutect2
- COL6A1 | c.2280T>C p.F760= | Silent (SNP) | VAF 32/1134 reads (3%) | called by muse, mutect2
- DMD | c.9414C>T p.L3138= | Silent (SNP) | VAF 22/590 reads (4%) | called by muse, mutect2
- GPR39 | c.606C>T p.P202= | Silent (SNP) | VAF 191/615 reads (31%) | catalogued as COSV61421600; called by muse, mutect2, varscan2
- PCNT | c.1698A>G p.L566= | Silent (SNP) | VAF 120/594 reads (20%) | called by muse, mutect2, varscan2
- PLEKHG3 | c.2904G>A p.Q968= (on ENST00000394691; = p.Q1024= on NM_001308147.2) | Silent (SNP) | VAF 30/406 reads (7%) | catalogued as rs1438688413; called by muse, mutect2
- SACS | c.6981G>A p.L2327= | Silent (SNP) | VAF 17/260 reads (7%) | called by muse, mutect2
- SH3GL3 | c.156A>G p.S52= | Silent (SNP) | VAF 16/63 reads (25%) | called by muse, mutect2, varscan2
- SLC25A53 | c.198G>A p.V66= | Silent (SNP) | VAF 14/336 reads (4%) | catalogued as COSV100656172, COSV62460642; called by muse, mutect2
- TMTC3 | c.2133G>A p.L711= | Silent (SNP) | VAF 19/157 reads (12%) | called by muse, mutect2, varscan2
- WRNIP1 | c.1788C>T p.A596= | Silent (SNP) | VAF 134/367 reads (37%) | called by muse, mutect2, varscan2
- TBC1D1 | c.1911-1046C>T | Intron (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
